Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8M6, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8M6-01A (Primary Tumor).

Operative Procedure:
Thymectomy via sternotomy.

Pre-Operative Diagnosis:
Mixed lymphocyte epithelial thymoma.

Post-Operative Diagnosis:
Same.

Specimen Received:
Thymus

Final Pathologic Diagnosis:
Thymus, thymectomy:
Thymoma, mixed lymphocytic and epithelial type with minimal invasion. See note.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimen is received fresh for Tissue Procurement with the patient's name, labeled "thymus", and consists of a 231.0 gm., 14.2 x 14.0 x 2.8 cm. portion of gray-yellow, lobular fat with an area of palpable induration. This area of induration has dimensions of 6.5 x 6.5 x 3.2 cm. The cut surface of the area outside of the induration is gray-yellow, glistening, and predominantly fatty with minimal amounts of interspersed fibrous tissue. The area of induration is inked blue, serially sectioned to reveal a variegated cut surface with focal areas that have a fish-flesh appearance. There are focal areas that are yellow with focal calcification. Intervening fibrosis is present. This area of induration grossly appears to extend to the inked margin. No normal thymic tissue can be grossly identified. Representative sections of aforementioned mass are submitted in cassettes "1" through "7" while a representative section of normal appearing fat is submitted in cassette "8".

Microscopic Description:

Histologic sections show encapsulated lobulated mass composed predominantly of small lymphocytes and large epithelial cells with vesicular nuclei and abundant pink cytoplasm. Few foci of thymoma are present in the surrounding adipose tissue. Focal necrosis with surrounding fibrohistiocytic reaction and hemosiderin deposition consistent with recent biopsy site is identified. These morphologic findings are consistent with mixed lymphocytic and epithelial thymoma with minimal invasion.

Taken: DOB: (Age: Gender: Male

ICD O-3
C43.9
Thymoma, type B2, malignant
8584/3
Path
Thymoma, mixed type, malignant
8582/3
Site: Thymus C37.9
QJ 6/10/14

Staging Discrepancy	✓	
Quality/Syncronous Primary Nodules	✓	
Case is (check):		

Source: NCI Genomic Data Commons file bf448fa5-00d5-415c-add2-6db6acbebdde (TCGA-X7-A8M6.C928D7B7-5B8C-4171-B02F-2DE8C7B9175B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).